MMRF case MMRF_1871 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8e39bdf0-044d-4e25-a7ac-14239117e580

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.4 years (25,338 days); ISS stage: II; Days to last known disease status: 902 days (2.5 years); Days to last follow up: 902 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 166 days; Days to treatment end: 166 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 167 days; Days to treatment end: 167 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -1 (ECOG 0): M Protein 4.43 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.598 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 41 mg/dL; Immunoglobulin G 53.7 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 4.92 µg/mL; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.73 mmol/L; Albumin 42 g/L; Total Protein 11.4 g/dL; Glucose 5.39 mmol/L; C-Reactive Protein 0.08 mg/dL.
- Day 97 (ECOG 0): M Protein 0.44 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.065 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.719 mg/dL; Immunoglobulin G 7.55 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.43 mmol/L; Albumin 35 g/L; Total Protein 6.2 g/dL; Glucose 4.57 mmol/L.
- Day 186 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.595 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.524 mg/dL; Immunoglobulin G 4.89 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 4.62 µg/mL; Lactate Dehydrogenase 4.98 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 6.22 mmol/L.
- Day 263 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.668 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.592 mg/dL; Immunoglobulin G 6.85 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 3.82 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 10.6 ×10⁹/L; Absolute Neutrophil 7.2 ×10⁹/L; Platelets 272 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 5.39 mmol/L.
- Day 356 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.558 mg/dL; Immunoglobulin G 6.47 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 1.98 µg/mL; Lactate Dehydrogenase 3.78 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 3.69 mmol/L.
- Day 446 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.984 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.753 mg/dL; Immunoglobulin G 5.03 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 10.6 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 4.13 mmol/L.
- Day 532: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.65 mg/dL; Immunoglobulin G 5.25 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 3.21 µg/mL; Lactate Dehydrogenase 3.9 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 12.8 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.43 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 4.9 mmol/L.
- Day 641 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.22 mg/dL; Immunoglobulin G 7.07 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 2.08 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 4.62 mmol/L.
- Day 713 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 6.77 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 109 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 6.11 mmol/L.
- Day 810: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.974 mg/dL; Immunoglobulin G 6.38 g/L; Immunoglobulin A 1.33 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 2.25 µg/mL; Lactate Dehydrogenase 3.58 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 2.28 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 4.62 mmol/L.
- Day 902: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.964 mg/dL; Immunoglobulin G 6.22 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 3.78 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.02 ×10⁹/L; Platelets 106 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 5.8 g/dL; Glucose 4.29 mmol/L.

Other clinical attributes
- Day -1: Weight: 61 kg; Height: 156 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Melanoma; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1871_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -1 day.
- Sample MMRF_1871_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
